Surgical pathology report (de-identified scan), TCGA case TCGA-WC-A87Y, project TCGA-UVM (Uveal Melanoma), tissue source site MD Anderson, specimen TCGA-WC-A87Y-01A (Primary Tumor).

Accession:

Specimen Date/Time:

DIAGNOSIS

(A) RIGHT GLOBE, ENUCLEATION: (1-30%) (61-90%)
CHOROIDAL MELANOMA, MIXED EPITHELIOID AND SPINDLED TYPE, 13 MM BASE.
VORTEX VEIN INVASION PRESENT
TUMOR EXTENDS EXTRAOCULARLY IN VORTEX VEIN (A2) *ICD-O-3*
Optic nerve negative for tumor.
Ciliary body negative for tumor.
See comment.

*Melanoma, epithelioid & spindle
cell mixed 8770/3
Site: Choroid C69.3
9/11/14*

COMMENT

The tumor is mitotically active at 1 per 10 high-power fields. The PAS is examined for intraocular structures.

GROSS DESCRIPTION

(A) RIGHT GLOBE - An intact globe (22 x 22 x 21 mm) has an intact 4.0 mm optic nerve. The anterior chamber is formed gray iris (10 x 11 mm) surrounding a round 6.0 mm pupil. The sclera is unremarkable. By transillumination a shadow is present from 1-3 o'clock present 6.0 mm from the optic nerve and 2.0 mm from the limbus. The shadow corresponds to a choroidal brown tumor with 13 mm base and 7.0 mm height. The vitreous is clear. The sclera beneath the tumor is grossly intact.

SECTION CODE: A1-A4, vortex vein and tissue in regions (superior temporal, superior nasal, inferior nasal, inferior temporal); A5, pupil-optic nerve section; A6 calotte with tumor; A7, additional calotte; A8, optic nerve margin and lens.

CLINICAL HISTORY

Melanoma

SNOMED CODES

T-AA000, M-87203

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not

Entire report and diagnosis completed by:

-----END OF REPORT-----

Criteria	10/25/13	Yes	No
ICD-A Discrepancy			✓
Just/Date/Time/Initials/Signature			
Case ID (for file)			

Source: NCI Genomic Data Commons file 719a7457-08f6-4699-9537-8118c1fd5304 (TCGA-WC-A87Y.BE3CE26C-C3EC-442E-A618-BB6DEC18C2E7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).